TARGET case TARGET-30-PATNWL — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Adrenal gland. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/53592794-5ba3-5d53-aef3-b1eedd3bc33e

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Age at index: 4 years; Vital status: Dead; Days to death: 1,079 days (3.0 years).

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C74.9; Tissue or organ of origin: Adrenal gland, NOS; Classification of tumor: primary; Age at diagnosis: 4.9 years (1,794 days); Year of diagnosis: 2010; Days to last follow up: 1,079 days (3.0 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: Low.
   Pathology details: Percent tumor nuclei: 90.
   Treatment given: Protocol identifier: ANBL00B1.
   Treatment given: Protocol identifier: ANBL0532.

Follow-up (2 entries)
- Days to follow up: 680 days (1.9 years); Days to first event: 680 days (1.9 years); First event: Relapse.
- Days to follow up: 1,079 days (3.0 years); Year of follow up: 2013.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.

Biospecimens (2 samples)
- Sample TARGET-30-PATNWL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PATNWL-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Validation_20230322.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 1079
- Protocol: ANBL00B1, ANBL0532
- Histology: Unfavorable
- MKI: Low
- ICDO Description: Adrenal gland, NOS Suprarenal gland Adrenal, NOS
- Site of Relapse: Metastases only
